Somatic mutation profile of tumor specimen TARGET-10-PAREGC-03A (aliquot TARGET-10-PAREGC-03A-01D) from TARGET case TARGET-10-PAREGC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,983 days).
Specimen TARGET-10-PAREGC-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ec002ad-7b89-4248-b978-b48472cc6612.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREGC-10A (Blood Derived Normal), aliquot TARGET-10-PAREGC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2e3798f-332d-418a-b40f-ec7660c73be3

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, 3'UTR 1, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.103A>T p.K35* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV57601825; called by muse, mutect2, varscan2
- CNTN6 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs753636512, COSV63165421; called by muse, mutect2, varscan2
- IGSF21 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs994196363, COSV99244932; called by muse, mutect2, varscan2
- IGLV10-54 | chr22:22215269 ins CC | In Frame Ins (INS) | VAF 9/30 reads (30%) | called by mutect2, varscan2
- PLAAT2 | c.*27C>A | 3'UTR (SNP) | VAF 34/101 reads (34%) | called by muse, mutect2, varscan2
- SYT7 | c.216-5059C>T | Intron (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
